Somatic mutation profile of tumor specimen TARGET-20-PARMMN-09A (aliquot TARGET-20-PARMMN-09A-02D) from TARGET case TARGET-20-PARMMN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,275 days).
Specimen TARGET-20-PARMMN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74cf3f11-73b5-48f6-ac1c-5dfc57be17d0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARMMN-14A (Bone Marrow Normal), aliquot TARGET-20-PARMMN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a020e40-5394-4a6c-b044-054ca4b8c7d3

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 2, Nonsense Mutation 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.188C>A p.P63H (on ENST00000377970; = p.P78H on NM_002467.6) | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104388738, COSV52376860, COSV52381519; called by muse, varscan2
- TET2 | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 72/181 reads (40%) | catalogued as rs745887194; called by muse, mutect2, varscan2
- SETD2 | c.3454_3455insT p.Q1152Lfs*4 | Frame Shift Ins (INS) | VAF 99/211 reads (47%) | called by mutect2, pindel*, varscan2
- TET2 | c.2702dup p.N901Kfs*2 | Frame Shift Ins (INS) | VAF 50/160 reads (31%) | called by mutect2, pindel, varscan2
- BCOR | c.1578G>A p.S526= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as rs770926725, COSV60700840; called by muse, mutect2, varscan2
